Gene-level copy-number profile of specimen HCM-BROD-0118-C16-85A from HCMI case HCM-BROD-0118-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: GX; Age at diagnosis: 46.0 years (16,790 days).
Specimen HCM-BROD-0118-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a206640-f693-4946-a1e8-732d66caa707.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0118-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/23f80716-92e7-4af7-aa66-522440fce87a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,602; copy number 2: 43,814; copy number 3: 5,593; copy number 4: 1,407; copy number 5: 139; copy number 6: 32; copy number 7: 70; copy number 8: 4; copy number 13: 61; copy number 18: 5; copy number 28: 180.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 491 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:42,892,396–43,234,956, 3 genes, copy number 5: RN7SKP82, GRXCR1, AC111198.1.
- chr4:59,533,786–59,834,167, 5 genes, copy number 5: Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P.
- chr4:64,275,257–66,897,371, 28 genes, copy number 5–7: TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, LINC02232, AC107058.1, EFL1P2, AC096754.1, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P.
- chr4:151,027,090–151,027,617, 1 gene, copy number 6: AK4P6.
- chr4:152,613,875–155,807,811, 68 genes, copy number 5 (broad region; genes not listed).
- chr8:108,131,100–114,318,911, 48 genes, copy number 5: AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1, Y_RNA, AC064802.1, AC025881.1.
- chr8:116,642,130–116,944,487, 6 genes, copy number 5: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD.
- chr9:32,455,302–34,050,244, 67 genes, copy number 6–8 (broad region; genes not listed).
- chr10:52,230,398–52,314,507, 1 gene, copy number 5 (within-gene range 3–5): PRKG1-AS1.
- chr17:13,494,032–14,421,472, 15 genes, copy number 6–7: HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74, CDRT15, AC005224.1, HS3ST3B1, AC005224.3, AC005224.2, AC022816.1.
- chr17:37,084,992–41,930,542, 246 genes, copy number 13–28 (broad region; genes not listed).
- chr18:79,863,668–79,951,657, 3 genes, copy number 5: KCNG2, AC114341.1, SLC66A2.

Autosomal genes at a single copy (total copy number 1): 6,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
